Somatic mutation profile of tumor specimen TCGA-N8-A4PP-01A (aliquot TCGA-N8-A4PP-01A-11D-A28R-08) from TCGA case TCGA-N8-A4PP, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Carcinosarcoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-N8-A4PP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 089e91ed-8092-4bb9-897c-e10fdfe6d5c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N8-A4PP-10A (Blood Derived Normal), aliquot TCGA-N8-A4PP-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db5c9f38-73c1-4161-982d-b002e1666555

The open-access MAF lists 117 somatic variants for this specimen: 82 protein-altering or splice-affecting, 33 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 33, Nonsense Mutation 6, In Frame Del 1, Intron 1, Splice Site 1, Splice Region 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYT1L | c.608A>C p.K203T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | hotspot (GDC flag); SIFT tolerated (0.22); PolyPhen probably damaging (0.997); catalogued as COSV101218522, COSV67710505, COSV67719870; called by muse, mutect2, varscan2
- PPP2R1A | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 14/55 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59042523, COSV59042723; called by muse, mutect2, varscan2
- RRAS2 | c.215A>T p.Q72L | Missense Mutation (SNP) | VAF 89/187 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs113954997, COSV56329169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 37/73 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTL9 | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs782766148, COSV100185216, COSV61007402; called by muse, mutect2, varscan2
- ACTR3 | c.493G>A p.G165S | Missense Mutation (SNP) | VAF 96/228 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); catalogued as rs1241778276, COSV54304174; called by muse, mutect2, varscan2
- ARHGEF25 | c.1478G>A p.R493Q | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as rs116051216; called by muse, mutect2, varscan2
- CYTH1 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 79/284 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs375897965, COSV63121360; called by muse, mutect2, varscan2
- EDNRB | c.1144T>G p.F382V (on ENST00000377211 / NM_001201397.1; = p.F292V on NM_000115.5) | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as CM021581, COSV57527910; called by muse, mutect2, varscan2
- EPB41L2 | c.1957C>T p.R653C | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs374441396; called by muse, mutect2, varscan2
- HIVEP3 | c.433C>T p.L145F | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs745675194; called by muse, mutect2, varscan2
- HNRNPD | c.549A>T p.K183N | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58313654; called by muse, mutect2, varscan2
- HOXD10 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs779016325, COSV50893286, COSV50893495; called by muse, mutect2, varscan2
- KPRP | c.1273C>T p.R425* | Nonsense Mutation (SNP) | VAF 124/398 reads (31%) | catalogued as rs375076533, COSV64222310; called by muse, mutect2, varscan2
- MIOS | c.1664A>G p.N555S | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.153); catalogued as rs370610296; called by muse, mutect2, varscan2
- MUC16 | c.22778C>G p.S7593C | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.54); catalogued as COSV67504576; called by muse, mutect2, varscan2
- NRN1 | c.140A>G p.D47G | Missense Mutation (SNP) | VAF 36/195 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as COSV55205878; called by muse, mutect2, varscan2
- OR8D1 | c.253T>G p.F85V | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100766621, COSV63441871; called by muse, mutect2, varscan2
- OR9G4 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.596); catalogued as rs147669235; called by muse, mutect2
- PAMR1 | c.1826G>A p.S609N (on ENST00000619888 / NM_001001991.3; = p.S626N on NM_015430.4) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.037); catalogued as rs894822042; called by muse, mutect2, varscan2
- PCLO | c.1685G>C p.G562A | Missense Mutation (SNP) | VAF 24/505 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100434624, COSV61634120; called by muse, mutect2
- PDGFRB | c.1949C>T p.S650L | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758280032, COSV55805130; called by muse, mutect2, varscan2
- PDPR | c.2210G>T p.R737L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV55355076; called by muse, mutect2
- RASA1 | c.1776+2T>C p.X592_splice | Splice Site (SNP) | VAF 11/29 reads (38%) | catalogued as COSV57191960; called by muse, mutect2, varscan2
- RBBP6 | c.3352G>A p.V1118I | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs1237159194; called by muse, mutect2, varscan2
- SON | c.4784C>T p.S1595F | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.102); catalogued as COSV51670701; called by muse, mutect2, varscan2
- TSHZ2 | c.1860C>G p.H620Q | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV61590811; called by muse, mutect2, varscan2
- UQCC1 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs981500822, COSV62902646; called by muse, mutect2, varscan2
- VPS72 | c.469C>G p.R157G | Missense Mutation (SNP) | VAF 20/410 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV63167896; called by muse, mutect2
- WNT4 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 45/234 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); catalogued as rs1370639387, COSV99268850; called by muse, mutect2, varscan2
- ADAM30 | c.726_746del p.Q242_I248del | In Frame Del (DEL) | VAF 16/60 reads (27%) | called by mutect2, pindel, varscan2
- ADGRG3 | c.905C>G p.S302* | Nonsense Mutation (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2, varscan2
- AVIL | c.1831A>G p.I611V | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRPF1 | c.2920T>G p.F974V | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- C10orf53 | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 7/78 reads (9%) | called by muse, mutect2
- C1orf87 | c.229A>G p.T77A | Missense Mutation (SNP) | VAF 50/195 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC6 | c.40G>C p.G14R | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCL13 | c.284C>G p.T95S | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- CELA2B | c.628T>C p.C210R | Missense Mutation (SNP) | VAF 62/249 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- COLGALT2 | c.482A>G p.D161G | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CWF19L2 | c.2425G>T p.D809Y | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DISP1 | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- DPP10 | c.2158T>G p.L720V | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- DRD3 | c.843G>C p.K281N | Missense Mutation (SNP) | VAF 90/265 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ENPP6 | c.277T>G p.Y93D | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- EPS15 | c.1852G>T p.D618Y | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- FASTKD3 | c.1582C>G p.L528V | Missense Mutation (SNP) | VAF 77/264 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- GET4 | c.850T>G p.F284V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GNRHR | c.321G>C p.W107C | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IRAK4 | c.264G>C p.L88F | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- ITGB1 | c.1878A>T p.Q626H | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- KRT18 | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- MMP25 | c.765C>A p.Y255* | Nonsense Mutation (SNP) | VAF 70/255 reads (27%) | called by muse, mutect2, varscan2
- MUC17 | c.8440A>T p.S2814C | Missense Mutation (SNP) | VAF 141/680 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- MYF6 | c.333G>C p.E111D | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- NAPG | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2
- NPR1 | c.1965C>G p.I655M | Missense Mutation (SNP) | VAF 62/207 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- NSDHL | c.812A>C p.E271A | Missense Mutation (SNP) | VAF 28/273 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- OR10Z1 | c.502T>G p.F168V | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OTUD7A | c.1985G>T p.G662V (on ENST00000307050 / NM_001382637.1; = p.G655V on NM_130901.3) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- PAQR7 | c.304C>A p.P102T | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PDCD4 | c.886G>T p.D296Y | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- PHKA2 | c.161T>G p.V54G | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PIWIL3 | c.284T>C p.I95T | Missense Mutation (SNP) | VAF 96/267 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PJA2 | c.1806G>C p.E602D | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.416); called by muse, mutect2
- PLAG1 | c.992C>A p.S331Y | Missense Mutation (SNP) | VAF 35/308 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- RAET1E | c.554C>A p.S185* | Nonsense Mutation (SNP) | VAF 45/91 reads (49%) | called by muse, mutect2, varscan2
- SH3PXD2B | c.156G>A p.Q52= | Splice Region (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2, varscan2
- SHOC1 | c.2635C>T p.P879S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- SIAH1 | c.778G>C p.D260H | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC12A3 | c.1758G>C p.W586C | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SORCS1 | c.3139A>T p.K1047* | Nonsense Mutation (SNP) | VAF 18/65 reads (28%) | called by muse, mutect2, varscan2
- STAT1 | c.1380C>G p.N460K | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TACC2 | c.2240T>C p.M747T | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBXAS1 | c.1438_1447del p.L480Vfs*2 | Frame Shift Del (DEL) | VAF 14/136 reads (10%) | called by mutect2, pindel
- TLR7 | c.342G>T p.K114N | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- VWA8 | c.3004G>A p.V1002M | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WASHC4 | c.3287C>G p.A1096G | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFP28 | c.1598A>T p.Y533F | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZFP90 | c.1237A>G p.M413V | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ZNF37A | c.423T>G p.N141K | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF622 | c.859G>C p.D287H | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCA13 | c.8553T>C p.I2851= | Silent (SNP) | VAF 25/123 reads (20%) | called by muse, mutect2, varscan2
- AMPH | c.1785G>A p.Q595= | Silent (SNP) | VAF 23/104 reads (22%) | catalogued as rs1459450099; called by muse, mutect2, varscan2
- APEX1 | c.942A>T p.L314= | Silent (SNP) | VAF 14/194 reads (7%) | called by muse, mutect2
- ASCL1 | c.579C>A p.I193= | Silent (SNP) | VAF 18/79 reads (23%) | called by muse, mutect2, varscan2
- ATP11B | c.1608A>G p.E536= | Silent (SNP) | VAF 36/121 reads (30%) | called by muse, mutect2, varscan2
- ATP13A4 | c.834C>T p.R278= | Silent (SNP) | VAF 52/333 reads (16%) | catalogued as rs376879092; called by muse, mutect2, varscan2
- BORCS6 | c.514C>T p.L172= | Silent (SNP) | VAF 12/43 reads (28%) | called by muse, mutect2, varscan2
- BRINP2 | c.114G>A p.A38= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as rs944890706; called by muse, mutect2, varscan2
- CCDC159 | c.507G>A p.E169= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV52259697; called by muse, mutect2, varscan2
- COL5A1 | c.792G>T p.T264= | Silent (SNP) | VAF 38/202 reads (19%) | catalogued as rs757360763, COSV65672475; ClinVar: likely benign; called by muse, mutect2, varscan2
- DAGLA | c.2991G>C p.S997= | Silent (SNP) | VAF 26/123 reads (21%) | called by muse, mutect2, varscan2
- FARSA | c.732C>A p.T244= | Silent (SNP) | VAF 26/94 reads (28%) | called by muse, mutect2, varscan2
- FLT1 | c.2178A>G p.E726= | Silent (SNP) | VAF 21/96 reads (22%) | called by muse, mutect2, varscan2
- HOXD9 | c.330C>T p.S110= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs1437856292, COSV50894628; called by muse, mutect2, varscan2
- HRNR | c.2436C>T p.G812= | Silent (SNP) | VAF 36/273 reads (13%) | catalogued as rs750503764; called by muse, mutect2, varscan2
- ITIH5 | c.2562A>G p.E854= | Silent (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2, varscan2
- NOVA2 | c.1311C>A p.G437= | Silent (SNP) | VAF 44/218 reads (20%) | catalogued as COSV54358984; called by muse, mutect2, varscan2
- NPR1 | c.2253C>A p.I751= | Silent (SNP) | VAF 68/183 reads (37%) | catalogued as rs770209942; called by muse, mutect2, varscan2
- PCDHA9 | c.1752G>A p.S584= | Silent (SNP) | VAF 61/199 reads (31%) | catalogued as rs782099893, COSV100968930; called by muse, mutect2, varscan2
- PIK3CG | c.87G>A p.A29= | Silent (SNP) | VAF 21/169 reads (12%) | catalogued as rs780581522, COSV63254643; called by muse, mutect2, varscan2
- RPL21 | c.6G>A p.T2= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs112351536; called by muse, mutect2, varscan2
- RRNAD1 | c.285G>A p.A95= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as rs548109086, COSV57461228; called by muse, mutect2, varscan2
- SCN10A | c.5394C>T p.I1798= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV71860754; called by muse, mutect2, varscan2
- SENP1 | c.813C>A p.S271= | Silent (SNP) | VAF 22/154 reads (14%) | called by muse, mutect2, varscan2
- SERTM1 | c.267T>C p.N89= | Silent (SNP) | VAF 25/97 reads (26%) | called by muse, mutect2, varscan2
- SLC16A11 | c.102T>C p.D34= (on ENST00000308009; = p.D10= on NM_153357.3) | Silent (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- SMARCC2 | c.1422A>C p.R474= | Silent (SNP) | VAF 16/186 reads (9%) | called by muse, mutect2
- TBCEL | c.624C>A p.A208= | Silent (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- TRANK1 | c.6645A>C p.T2215= | Silent (SNP) | VAF 20/74 reads (27%) | called by muse, mutect2, varscan2
- TRIP12 | c.2841T>C p.C947= | Silent (SNP) | VAF 12/109 reads (11%) | called by muse, mutect2, varscan2
- UGT1A4 | c.663C>A p.S221= | Silent (SNP) | VAF 28/217 reads (13%) | called by muse, mutect2, varscan2
- XPNPEP3 | c.1341A>C p.V447= | Silent (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2, varscan2
- ZFHX4 | c.8022T>C p.H2674= | Silent (SNP) | VAF 25/130 reads (19%) | called by muse, mutect2, varscan2
- OR2U1P | n.757A>G | RNA (SNP) | VAF 14/82 reads (17%) | called by muse, mutect2, varscan2
- TTN | c.10360+2360C>A | Intron (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
